FM case AD15092 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/181da6d2-1270-4741-a83d-5ec3e6a48213

Male, 70.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the head, face or neck; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 83% (pathologist estimate recorded by GDC). Sample type: Tumor.
